CCDI case PBCKCZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/db0bb3da-d955-447f-86ee-2517efce4fa7

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Smooth muscle tumor of uncertain malignant potential: ICD-O-3 morphology code: 8897/1; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 15.5 years (5,675 days).

Biospecimens (3 samples)
- Samples 0DUUP1, 0DUUQ7 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUUPJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
